Somatic mutation profile of tumor specimen MP2PRT-PAUMTE-TMP1-A (aliquot MP2PRT-PAUMTE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUMTE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,946 days).
Specimen MP2PRT-PAUMTE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51370808-2e3b-4ce0-9e6c-53e08f8a4ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMTE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMTE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5f5c93-f586-41cc-8d7e-c2bc6afdfde6

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/366 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ANK3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769188895, COSV55084703; called by muse, mutect2, varscan2
- AP002512.3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 102/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54408796; called by muse, mutect2, varscan2
- CSMD1 | c.2122C>T p.R708* (on ENST00000520002; = p.R707* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 85/429 reads (20%) | catalogued as COSV59352312; called by muse, mutect2, varscan2
- GSX2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 232/1072 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs921321898; called by mutect2, varscan2
- MLF1 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV63032698; called by muse, mutect2, varscan2
- MUC12 | c.896C>T p.T299M (on ENST00000379442; = p.T156M on NM_001164462.1) | Missense Mutation (SNP) | VAF 87/431 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.551); catalogued as rs370911866; called by muse, mutect2, varscan2
- PDGFRA | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 146/700 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as rs779173667, CM102817, COSV57269953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKN | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 85/581 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV58201347; called by muse, varscan2
- SHROOM2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 130/456 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1425621471, COSV101098081; called by muse, mutect2, varscan2
- SOX9 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 188/938 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs778788591; called by muse, mutect2, varscan2
- TENM3 | c.5629C>T p.R1877W | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771356366, COSV69310319; called by muse, mutect2, varscan2
- THEMIS | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 98/552 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.293); catalogued as COSV64069889; called by muse, mutect2, varscan2
- ADRA2A | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 222/948 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CHORDC1 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EVI5L | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKD1 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 87/564 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTPRK | c.1881C>T p.I627= | Splice Region (SNP) | VAF 61/349 reads (17%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 138/561 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- Z82206.1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- CRMP1 | c.360C>T p.F120= | Silent (SNP) | VAF 74/398 reads (19%) | catalogued as rs144668952, COSV61478618; called by muse, mutect2, varscan2
- KIF13B | c.5013G>A p.P1671= | Silent (SNP) | VAF 202/951 reads (21%) | catalogued as rs1244328683; called by muse, mutect2, varscan2
- RNF112 | c.1488C>T p.L496= | Silent (SNP) | VAF 151/533 reads (28%) | called by muse, mutect2, varscan2
- SLC5A6 | c.96C>T p.F32= | Silent (SNP) | VAF 180/575 reads (31%) | catalogued as rs753660328, COSV60159261; called by muse, mutect2, varscan2
- TBC1D30 | c.1128C>T p.F376= (on ENST00000542120; = p.F213= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/268 reads (26%) | catalogued as rs1246958491; called by muse, mutect2, varscan2
- TTC5 | c.723G>A p.G241= | Silent (SNP) | VAF 95/440 reads (22%) | called by muse, mutect2, varscan2
- ZNF804B | c.606G>A p.Q202= | Silent (SNP) | VAF 95/346 reads (27%) | called by muse, mutect2, varscan2
